Somatic mutation profile of tumor specimen MP2PRT-PATKBF-TMP1-A (aliquot MP2PRT-PATKBF-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATKBF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (861 days).
Specimen MP2PRT-PATKBF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8a8d418-fef0-437f-8e9e-89d360b720d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATKBF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATKBF-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba2c2fa8-a870-4639-9cc6-b140dd69d281

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Ins 2, Silent 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3B | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 171/488 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.164); catalogued as rs759777486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPG | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 233/672 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774213821, COSV54738751; called by muse, mutect2, varscan2
- MYO15B | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 280/790 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.035); catalogued as rs1356014552; called by muse, mutect2, varscan2
- TJAP1 | c.1246C>T p.R416W (on ENST00000372445 / NM_001146016.1; = p.R406W on NM_080604.3) | Missense Mutation (SNP) | VAF 228/622 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs41281810; called by muse, varscan2
- COL9A2 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 165/474 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ELF1 | c.1766dup p.Q590Tfs*53 | Frame Shift Ins (INS) | VAF 143/461 reads (31%) | called by mutect2, pindel, varscan2
- PAX5 | c.579_580insTCCTCGCGAC p.T194Sfs*52 | Frame Shift Ins (INS) | VAF 90/365 reads (25%) | called by pindel, varscan2
- SMOC2 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 162/479 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- GRIN2D | c.180C>T p.P60= | Silent (SNP) | VAF 12/383 reads (3%) | called by muse, mutect2
- HUNK | c.705C>T p.L235= | Silent (SNP) | VAF 184/449 reads (41%) | catalogued as rs1437617952, COSV54228606; called by muse, mutect2, varscan2
- TRDJ1 | chr14:22449125 ins GGGGGGAGAT | 5'Flank (INS) | VAF 22/98 reads (22%) | called by pindel, varscan2
- UNC13B | c.762-5434A>G | Intron (SNP) | VAF 12/442 reads (3%) | called by muse, mutect2
